Somatic mutation profile of tumor specimen C3L-00949-01 (aliquot CPT0016370006) from CPTAC case C3L-00949, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 64.5 years (23,564 days).
Specimen C3L-00949-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b98af474-c540-41b1-9308-31272df35cfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00949-72 (Blood Derived Normal), aliquot CPT0016440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cc96310-eb43-437b-a0cf-6db2d43a9492

The open-access MAF lists 75 somatic variants for this specimen: 45 protein-altering or splice-affecting, 19 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 19, Intron 6, Nonsense Mutation 5, RNA 4, Frame Shift Del 3, Splice Region 1, In Frame Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 93/506 reads (18%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, pindel, varscan2
- NIPBL | c.5335C>T p.R1779* | Nonsense Mutation (SNP) | VAF 60/328 reads (18%) | catalogued as rs587783971, COSV56949230; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 64/339 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BAHD1 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101346802; called by muse, mutect2, varscan2
- CARD9 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs371061371; called by muse, mutect2, varscan2
- CASKIN1 | c.3184C>T p.R1062W | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1381225305, COSV58216975; called by muse, mutect2, varscan2
- CFAP99 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as rs1267764959; called by muse, mutect2, varscan2
- DDR1 | c.1744G>A p.G582R (on ENST00000324771; = p.G545R on NM_001954.4) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753668090; called by muse, mutect2, varscan2
- FAM222B | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs376632053; called by muse, mutect2, varscan2
- FBH1 | c.509C>T p.T170M (on ENST00000362091 / NM_178150.3; = p.T221M on NM_032807.4) | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs773482471; called by muse, mutect2, varscan2
- GATA1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 94/510 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64962541; called by muse, mutect2, varscan2
- LOX | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV50240647; called by muse, mutect2, varscan2
- PIK3CB | c.3146T>G p.L1049R | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV56690569; called by muse, mutect2, varscan2
- PTH2R | c.984G>T p.L328= | Splice Region (SNP) | VAF 20/97 reads (21%) | catalogued as COSV55920318; called by muse, varscan2
- PTPN13 | c.5491G>T p.G1831W (on ENST00000411767 / NM_080683.3; = p.G1812W on NM_006264.3) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57417227; called by muse, mutect2
- RAB3IL1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs536709910, COSV57117239; called by muse, mutect2, varscan2
- TAS2R46 | c.750G>A p.W250* | Nonsense Mutation (SNP) | VAF 38/189 reads (20%) | catalogued as rs376068759; called by muse, varscan2
- TMEM131L | c.2152G>A p.V718M | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs375690251; called by muse, mutect2, varscan2
- TTC28 | c.4690G>A p.G1564S | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1217081914; called by muse, mutect2, varscan2
- TTN | c.40049C>A p.S13350Y (on ENST00000591111; = p.S5926Y on NM_003319.4) | Missense Mutation (SNP) | VAF 40/184 reads (22%) | PolyPhen possibly damaging (0.858); catalogued as COSV100621600; called by muse, mutect2, varscan2
- TXNIP | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV65220939; called by muse, mutect2, varscan2
- UNC13C | c.2396C>T p.S799F | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs899959296; called by muse, mutect2, varscan2
- YTHDC1 | c.1588C>T p.R530W (on ENST00000344157 / NM_001031732.4; = p.R512W on NM_133370.4) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs376343599; called by muse, mutect2, varscan2
- ZNF804A | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 25/194 reads (13%) | catalogued as rs772974941, COSV56437401, COSV56474195; called by muse, mutect2, varscan2
- ALDH3B1 | c.164C>A p.S55* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- ARID5B | c.1511C>A p.S504* | Nonsense Mutation (SNP) | VAF 33/192 reads (17%) | called by muse, mutect2, varscan2
- CLTC | c.224_250+13del p.X75_splice | Splice Site (DEL) | VAF 56/267 reads (21%) | called by mutect2, pindel
- DMD | c.2825T>C p.M942T | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, varscan2
- FREM3 | c.4670T>C p.L1557P | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK4 | c.1088T>C p.I363T | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- KCTD5 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MACO1 | c.1333A>G p.M445V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2
- MTOR | c.6398G>A p.C2133Y | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- NPAS1 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR9A2 | c.413T>A p.I138N | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PKHD1 | c.11302G>T p.D3768Y | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTEN | c.800_801del p.K267Rfs*30 | Frame Shift Del (DEL) | VAF 46/239 reads (19%) | called by mutect2, pindel, varscan2
- RNF213 | c.12746G>A p.G4249D | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SETX | c.653A>T p.K218M | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SLC3A2 | c.738del p.R247Vfs*5 | Frame Shift Del (DEL) | VAF 22/116 reads (19%) | called by pindel, varscan2
- TAAR1 | c.848C>G p.P283R | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2
- TPPP | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- TUT7 | c.960_967del p.K320Nfs*22 | Frame Shift Del (DEL) | VAF 34/127 reads (27%) | called by mutect2, pindel, varscan2
- UPF1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ZNF394 | c.1058A>G p.H353R | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC1 | c.4041C>T p.A1347= | Silent (SNP) | VAF 42/222 reads (19%) | catalogued as rs1165676104, COSV60680264; called by muse, mutect2, varscan2
- AP2B1 | c.2472G>C p.V824= | Silent (SNP) | VAF 29/187 reads (16%) | called by muse, mutect2, varscan2
- C1orf94 | c.1737C>T p.S579= (on ENST00000488417 / NM_001134734.2; = p.S389= on NM_032884.5) | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as rs147248695; called by muse, mutect2, varscan2
- CASP8AP2 | c.99C>T p.Y33= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as rs567255449; called by muse, mutect2, varscan2
- DHRS7 | c.573C>T p.I191= | Silent (SNP) | VAF 65/313 reads (21%) | catalogued as COSV99381721; called by muse, mutect2, varscan2
- GABRB3 | c.513C>T p.D171= | Silent (SNP) | VAF 102/510 reads (20%) | catalogued as rs200507900; called by muse, mutect2, varscan2
- MCOLN1 | c.1581C>T p.P527= | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as rs900817572; ClinVar: likely benign; called by muse, mutect2
- MYBPC2 | c.2451G>A p.A817= | Silent (SNP) | VAF 55/260 reads (21%) | catalogued as rs572390648, COSV63093681; called by muse, mutect2, varscan2
- PAPLN | c.2916C>T p.D972= (on ENST00000554301; = p.D945= on NM_173462.4) | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as rs376194083; called by muse, mutect2, varscan2
- PCDHB5 | c.1527C>T p.N509= | Silent (SNP) | VAF 184/849 reads (22%) | catalogued as rs377744960; called by muse, mutect2, varscan2
- PRDM6 | c.687G>A p.A229= | Silent (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- RHBDL3 | c.792A>G p.A264= | Silent (SNP) | VAF 31/169 reads (18%) | called by muse, mutect2, varscan2
- RNF207 | c.1218C>A p.I406= | Silent (SNP) | VAF 37/185 reads (20%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.264C>T p.Y88= | Silent (SNP) | VAF 39/254 reads (15%) | catalogued as COSV60515298, COSV60520287; called by muse, mutect2, varscan2
- TAF1C | c.1251G>A p.P417= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs765355608; called by muse, mutect2, varscan2
- TET1 | c.1743G>A p.P581= | Silent (SNP) | VAF 66/270 reads (24%) | catalogued as rs532096691, COSV101017955; called by muse, mutect2, varscan2
- TEX15 | c.6336T>C p.F2112= (on ENST00000256246; = p.F2495= on NM_001350162.2) | Silent (SNP) | VAF 14/120 reads (12%) | called by muse, varscan2
- TUBA3C | c.309C>T p.Y103= | Silent (SNP) | VAF 37/200 reads (19%) | catalogued as rs114178008, COSV67139668; called by muse, mutect2, varscan2
- ZNF536 | c.762G>A p.P254= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs763724071; called by muse, mutect2, varscan2
- ADGRG5 | n.347C>T | RNA (SNP) | VAF 18/85 reads (21%) | catalogued as rs932260550; called by muse, mutect2, varscan2
- CEROX1 | n.3264C>T | RNA (SNP) | VAF 16/64 reads (25%) | catalogued as rs1052654305; called by muse, mutect2, varscan2
- DIP2C | c.85+38324C>T | Intron (SNP) | VAF 23/452 reads (5%) | catalogued as rs1463239196; called by muse, mutect2
- GNG7 | c.-78+3071G>T | Intron (SNP) | VAF 121/638 reads (19%) | called by muse, mutect2, varscan2
- ING2 | c.172+885C>T | Intron (SNP) | VAF 37/165 reads (22%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85489C>T | Intron (SNP) | VAF 76/366 reads (21%) | catalogued as rs114511100, COSV72277362; called by muse, varscan2
- PDSS1 | c.1027-1810C>G | Intron (SNP) | VAF 17/168 reads (10%) | called by muse, mutect2
- POLG | c.2480+31G>C | Intron (SNP) | VAF 124/544 reads (23%) | called by muse, mutect2, varscan2
- PRAME | chr22:22563807 C>T | 5'Flank (SNP) | VAF 24/118 reads (20%) | catalogued as rs748848805; called by muse, mutect2
- SSTR5-AS1 | n.1204G>A | RNA (SNP) | VAF 28/162 reads (17%) | catalogued as rs771972397; called by muse, mutect2, varscan2
- TSBP1-AS1 | n.93G>T | RNA (SNP) | VAF 19/95 reads (20%) | called by mutect2, varscan2
